Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A6II, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A6II-01A (Primary Tumor).

[page 1 of 6]
Document Type:
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

Anat Path Reports

ICD-0-3
Carcinoma, squamous
Cell NBS 8670/3
Site: Floor of mouth
8604.9
JW 6/12/13

*** Final Report ***

(Verified)

Patient Name:

Acc #:

MRN:

DOB:

Head and Neck

Location:

Gender:

M

Collected:

Client:

Received:

Submitting Phys:

Reported:

Copy To Phys:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. MEDIAL TONGUE MARGIN, , EXCISION, A1FS:

- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

B. TONGUE MARGIN, BASE, EXCISION, B1FS:

- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

C. GINGIVAL MARGIN, LEFT, EXCISION, C1FS:

- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

D. GINGIVAL MARGIN, RIGHT, EXCISION, D1FS:

- BENIGN SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

E. TONGUE MARGIN, DEEP, EXCISION, E1FS:

- BENIGN SKELETAL MUSCLE.
- NEGATIVE FOR INVASIVE CARCINOMA.

F. GENIAL HYOID TUBERCLE, EXCISION, F1FS:

- BENIGN SKELETAL MUSCLE AND FIBROUS TISSUE.
- NEGATIVE FOR INVASIVE CARCINOMA.

G. FLOOR OF MOUTH AND TONGUE, COMPOSITE RESECTION:

- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (4.3 X 4.2 X 1.6CM).
- PERINEURAL INVASION IS PRESENT.
- ALL SURGICAL MARGINS (SEE SEPARATELY SUBMITTED PARTS A-F) NEGATIVE FOR CARCINOMA.
- SEE SYNOPSIS REPORT.

H. NECK CONTENTS, LEFT LEVEL I, NECK DISSECTION:

- TWO OF FIVE LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (2/5).

H&P/PA Discrepancy		☒

[page 2 of 6]
- SALIVARY GLAND PARENCHYMA WITH CHRONIC SIALADENITIS.

I. LYMPH NODES, LEFT LEVEL II, NECK DISSECTION:

- ONE LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA (1/1).
- EXTRANODAL EXTENSION (>2MM) IS PRESENT.

J. NECK CONTENTS, RIGHT LEVEL I, NECK DISSECTION:

- ONE OF THREE LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (1/3).
- SALIVARY GLAND PARENCHYMA WITH CHRONIC SIALADENITIS.

K. LYMPH NODES, SUBMENTAL, NECK DISSECTION:

- THREE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/3).

L. LYMPH NODES, ADDITIONAL LEFT NECK LEVEL II, EXCISION:

- ELEVEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/11).

M. LYMPH NODES, LEFT LEVEL III, NECK DISSECTION:

- SEVENTEEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/17).

N. LYMPH NODES, LEFT LEVEL IV, NECK DISSECTION:

- THREE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/3).

O. LYMPH NODES, RIGHT LEVEL II, NECK DISSECTION:

- FIVE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/5).

Electronically Signed by

Assisted by:

Synoptic Worksheet

G. Composite resection of floor of mouth and tongue, black stitch anterior (fresh for research study):

Clinical History:	No neoadjuvant therapy
Specimen:	Ventral surface of tongue, not otherwise specified (NOS) Floor of mouth, NOS
Received:	Fresh
Procedure:	Glossectomy: Composite resection: Ventral tongue, Floor of mouth and suprahyoid musculature Neck (lymph node) dissection: Submental, Right Level I, II and Left Level I-IV
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 7.0 cm Additional dimension: 5.5 cm Additional dimension: 5.2 cm
Specimen Laterality:	Midline
Tumor Site:	Ventral surface of tongue, NOS Floor of mouth, NOS
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 4.3 cm Additional dimension: 4.2 cm Additional dimension: 1.6 cm
Tumor Thickness (pT1 and pT2 tumors):	Tumor thickness: 1.6 mm
Macroscopic Extent of Tumor:	Extension into extrinsic tongue musculature identified at time of surgery by

[page 3 of 6]
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G2: Moderately differentiated
Microscopic Tumor Extension:	Infiltration of skeletal muscle bundles and oral salivary gland tissue
Margins:	Margins uninvolved by invasive carcinoma Margins uninvolved by carcinoma in situ (includes moderate and severe dysplasia)
Treatment Effect:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Present
Lymph Nodes, Extranodal Extension:	Present
Pathologic Staging (pTNM):	
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT4a: Moderately advanced local disease. Lip: Tumor invades through cortical bone, inferior alveolar nerve, floor of mouth, or skin of face, ie, chin or nose. Oral cavity: Tumor invades adjacent structures only
Regional Lymph Nodes (pN):	pN2c: Metastasis in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension Number of regional lymph nodes examined: 58 Number of regional lymph nodes involved: 4 Size (greatest dimension) of the largest positive lymph node: 2.0 cm
Distant Metastasis (pM):	Not applicable

Clinical History

Oral cancer

Specimen(s) Received

A: Medial tongue, stitch anterior
B: Base of tongue, stitch anterior
C: Left gingival margin, stitch anterior
D: Right gingival margin
E: Deep tongue margin
F: Genial hyoid tubercle
G: Composite resection of floor of mouth and tongue, black stitch anterior (fresh for research study)
H: Left neck level #1
I: Left neck level #2
J: Right neck level #1
K: Submental neck content (fresh)
L: Additional left neck level 2
M: Left neck level 3
N: Left neck level 4
O: Right neck level 2

Gross Description

Specimen A is received fresh along with patient's name, medical record number and as medial tongue margin frozen section, stitch anterior. The specimen consists of a fragment of soft tissue measuring 6.6 x 1.0 x 0.3 cm. A stitch is present with the specimen and designated as anterior. The stitch area is inked blue. The specimen is submitted for intraoperative consultation and entirely submitted in cassette A1FS. (Dictated by

Specimen B is received fresh along with patient's name, medical record number and as base of tongue margin, stitch anterior, frozen section. The specimen consists of a fragment of soft tissue measuring 5.8 x 0.7 x 0.6 cm. A stitch is present with the specimen and designated as anterior. The stitch area is inked blue. The specimen is submitted for intraoperative consultation and entirely submitted in cassette B1FS. (Dictated by

[page 4 of 6]
Specimen C is received fresh along with patient's name, medical record number and as 6 to left gingival margin, stitch anterior, frozen section. The specimen consists of a fragment of soft tissue measuring 5.5 x 0.8 x 0.3 cm. A stitch is present with the specimen and designated as anterior. The stitch area is inked blue. The specimen is submitted for intraoperative consultation and entirely submitted in cassette C1FS. (Dictated by

Specimen D is received fresh along with patient's name, medical record number and as right gingival margin, frozen section. The specimen consists of a fragment of soft tissue measuring 1.2 x 0.7 x 0.2 cm. The specimen is submitted for intraoperative consultation and entirely submitted in cassette D1FS. (Dictated by

Specimen E is received fresh along with patient's name, medical record number and as deep tongue margin, frozen section. The specimen consists of a small fragment of soft tissue measuring 2.0 x 0.8 x 0.3 cm. The specimen is submitted for intraoperative consultation and entirely submitted in cassette E1FS. (Dictated by

Specimen F is received fresh along with patient's name, medical record number and as genial hypoid tubercle, frozen section. The specimen consists of multiple soft tissue fragments measuring 1.0 x 0.8 x 0.3 cm in aggregate. The specimen is submitted for intraoperative consultation and entirely submitted in cassette F1FS. (Dictated by

Specimen G is received fresh along with patient's name, medical record number and as composite resection of floor of mouth and tongue, black stitch anterior. The specimen consists of a portion of left tongue with the floor of mouth measuring 7.0 cm from anterior-to-posterior, 5.5 cm from lateral-to-medial and 5.2 cm from superior-to-inferior. An ill-defined friable mass lesion arising from the floor of mouth is identified in the specimen. This mass lesion is invading into the ventral and lateral surfaces of the tongue. It also apparently crosses the midline of the tongue. This mass lesion measures 4.3 cm from anterior-to-posterior, 4.2 cm from superior-to-inferior, 1.6 cm from medial-to-lateral. The cut surface of this mass lesion shows a homogeneous white appearance. This mass lesion is abutting the lateral periosteum surface and also medial and inferior surface. Within the specimen, there is also a separate small fragment of squamous mucosa is sutured and attached with the specimen. This small fragment of mucosa tissue is unremarkable. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

- G1: Mass lesion in relation to the medial surface (black)
- G2: Mass lesion in relation to the lateral periosteum surface (blue)
- G3: Mass lesion in relation to the inferior surface (green)
- G4: Mass in relationship to the superior surface (red)
- G5: A representative section of mass lesion
- G6: A representative section from the attached separate small fragment of tongue mucosa

Specimen H is received in formalin along with patient's name, medical record number and as left neck level 1. The specimen consists of a fragment of fibroadipose tissue measuring 4.5 x 3.5 x 2.5 cm. A portion of salivary gland tissue is identified within the specimen. A total of 5 potential lymph nodes are identified within the specimen. The largest one measures 1.2 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

- H1: One lymph node, bisected
- H2: One potential lymph node, bisected
- H3: One potential lymph node, bisected
- H4-H7: One lymph node, quadrisected
- H8-H10: One lymph node, trisected
- H11: Representative section of the normal-appearing salivary gland tissue

Specimen I is received in formalin along with patient's name, medical record number and labeled as left neck level 2. The specimen consists of a grossly malignant lymph node which measures 2.0 x 1.1 x 0.9 cm. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

- I1-I3: Representative lymph node

[page 5 of 6]
Specimen J is received fresh along with patient's name, medical record number and as right neck level #1. The specimen consists of a fragment of soft tissue measuring 6.0 x 2.5 x 1.0 cm. A total of 3 potential lymph nodes are identified in the specimen. The largest one measures 1.5 cm in diameter. Within this largest potential lymph node, there is a well-circumscribed firm white nodule which measures 0.9 cm in diameter. The two potential lymph nodes are grossly unremarkable. The rest of the specimen is composed of a salivary gland. The parenchyma of the salivary gland tissue is unremarkable. Representative sections are submitted as follows. Representative section from the largest lymph node with the nodular lesion is submitted for tumor bank. (Dictated by

CASSETTE SUMMARY:

J1, J2: Entirely submitted largest lymph node with the white nodule
J3: A potential lymph node, bisected
J4: A potential lymph node
J5: Representative section from the salivary gland

Specimen K is received fresh along with patient's name, medical record number and as submental neck contents. The specimen consists of a fragment of fibroadipose tissue which measures 4.0 x 1.6 x 1.0 cm. A total of 5 potential lymph nodes are identified. The largest one measures 1.4 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

K1: One potential lymph node, bisected
K2: One potential lymph node, bisected
K3: One potential lymph node, bisected
K4: Two potential lymph nodes

Specimen L is received fresh along with patient's name, medical record number and as left neck level 2 additional, fresh. The specimen consists of a fragment of soft tissue measuring 3.5 x 2.0 x 1.3 cm. A total of 11 potential lymph nodes are identified within the specimen. The largest one measures 1.6 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

L1: One potential lymph node, bisected
L2: One potential lymph node, bisected
L3: One potential lymph node, bisected
L4: Two potential lymph nodes
L5: Two potential lymph nodes
L6: Two potential lymph nodes
L7: Two potential lymph nodes

Specimen M is received fresh along with patient's name, medical record number and as left neck level 3, fresh. The specimen consists of two fragments of fibroadipose tissue measuring 3.5 x 3.0 x 1.5 cm in aggregate. A total of 17 potential lymph nodes are identified in the specimen. The largest one measures 1.9 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

M1: One potential lymph node, bisected
M2: One potential lymph node, bisected
M3: One potential lymph node, bisected
M4: One potential lymph node, bisected
M5: One potential lymph node, bisected
M6-M11: Each cassette has two potential lymph nodes

Specimen N is received fresh along with patient's name, medical record number and as left neck level 4, fresh. The specimen consists of a fragment of fibroadipose tissue measuring 3.0 x 2.5 x 1.0 cm. A total of 3 potential lymph nodes are identified in the specimen. The largest one measures 1.0 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

[page 6 of 6]
N1: One potential lymph node, bisected
N2: One potential lymph node, bisected
N3: One potential lymph node

Specimen O is received fresh along with patient's name, medical record number and as right level 2, fresh. The specimen consists of a fragment of soft tissue measuring 3.4 x 1.5 x 1.2 cm. A total of 5 potential lymph nodes are identified in the specimen. The largest one measures 1.8 cm in diameter. Representative sections are submitted as follows. (Dictated by

CASSETTE SUMMARY:

O1-O3: Entirely submitted largest lymph node
O4: One lymph node, bisected
O5-O7: Each cassette has one potential lymph node

Intraoperative Consult Diagnosis

A1FS: MEDIAL TONGUE MARGIN, (FROZEN SECTION): BENIGN.
B1FS: BASE OF TONGUE MARGIN, (FROZEN SECTION): BENIGN.
C1FS: LEFT GINGIVAL MARGIN, (FROZEN SECTION): BENIGN.
D1FS: RIGHT GINGIVAL MARGIN, (FROZEN SECTION): BENIGN
E1FS: DEEP TONGUE MARGIN, (FROZEN SECTION): BENIGN.
F1FS: GENIAL HYOID TUBERCLE, (FROZEN SECTION): BENIGN.

Frozen section results were communicated to the surgical team and were repeated back by on
at In at

Pathologist:

Microscopic Description

Microscopic examination performed.

Source: NCI Genomic Data Commons file 04c2c5e0-01fd-441d-bf4d-c0b38fe19f17 (TCGA-QK-A6II.361EB258-E228-41DF-9C89-08FFBE099782.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).